Somatic mutation profile of tumor specimen C3L-06349-01 (aliquot CPT0362770009) from CPTAC case C3L-06349, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 74.5 years (27,208 days).
Specimen C3L-06349-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9713c94-f3e0-4f54-98aa-c8517bd9a10a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06349-31 (Blood Derived Normal), aliquot CPT0362870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba6cff7c-b545-4b7f-9e8d-3d4c642b78f6

The open-access MAF lists 2,707 somatic variants for this specimen: 1,706 protein-altering or splice-affecting, 904 silent, 97 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,566, Silent 904, Nonsense Mutation 101, Intron 62, Splice Region 22, Splice Site 10, 5'Flank 10, 3'UTR 9, 3'Flank 7, RNA 7, Frame Shift Del 5, 5'UTR 2.

Variants (750 of 2,707; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA3 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 49/381 reads (13%) | hotspot (GDC flag); catalogued as rs770780950, COSV60693907; called by muse, mutect2, varscan2
- F11 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1262002209, CM053239, COSV53005235; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRBA | c.2479C>T p.R827* | Nonsense Mutation (SNP) | VAF 24/336 reads (7%) | catalogued as rs779575307, COSV63955560; ClinVar: pathogenic; called by muse, mutect2
- NEXMIF | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 47/462 reads (10%) | catalogued as rs878854425, COSV50022161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 28/276 reads (10%) | catalogued as rs137853001, CM012633, COSV57282024; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PDHA1 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 46/448 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555933954, COSV63328622; ClinVar: likely pathogenic; called by muse, mutect2
- PGR | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 37/276 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1000609240, COSV54795429; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 37/274 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- RP1L1 | c.3022C>T p.Q1008* | Nonsense Mutation (SNP) | VAF 76/497 reads (15%) | catalogued as rs756996764, COSV66755966; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs118192160, CM061939, CM140861, COSV62087706, COSV62099686; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN8A | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 50/472 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1555226375; ClinVar: likely pathogenic; called by muse, mutect2
- USP9X | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 30/265 reads (11%) | catalogued as rs869025592, CM161665, COSV61071116; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1217G>A p.G406D (on ENST00000373993 / NM_138932.2; = p.G398D on NM_014576.4) | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.726); catalogued as rs768672322; called by muse, mutect2, varscan2
- AAR2 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 58/411 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57924943; called by muse, mutect2, varscan2
- AATK | c.757G>A p.D253N (on ENST00000326724 / NM_001080395.3; = p.D150N on NM_004920.2) | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1369774528; called by muse, mutect2, varscan2
- ABCC9 | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 26/375 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs1195562877; called by muse, mutect2
- ABCG2 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV52949281; called by muse, mutect2, varscan2
- ABCG2 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 56/398 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52943560; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 56/402 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs749167670, COSV99865401; called by muse, varscan2
- ABI3BP | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52532135; called by muse, mutect2
- AC008397.2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs201157838; called by muse, mutect2, varscan2
- ACOT11 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs753713724; called by muse, mutect2, varscan2
- ACOT12 | c.1373G>A p.R458K | Missense Mutation (SNP) | VAF 22/299 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56898743; called by muse, mutect2
- ADAM18 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV55847835; called by muse, mutect2
- ADAM2 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 20/248 reads (8%) | catalogued as rs1398874416; called by muse, mutect2
- ADAMTS10 | c.2194G>C p.V732L | Missense Mutation (SNP) | VAF 41/316 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as COSV99547589; called by muse, mutect2, varscan2
- ADAMTS18 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 52/463 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51418182; called by muse, mutect2, varscan2
- ADAMTS20 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 41/462 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV99061805; called by muse, mutect2
- ADAMTS5 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99537957; called by muse, mutect2, varscan2
- ADD2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 43/468 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs782626804, COSV52471635; called by muse, mutect2
- ADGRA1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 64/466 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs753948568; called by muse, varscan2
- ADGRB3 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 56/379 reads (15%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.921); catalogued as rs745590202, COSV65385300; called by muse, mutect2, varscan2
- ADGRB3 | c.3571G>A p.D1191N | Missense Mutation (SNP) | VAF 25/273 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53235644; called by muse, mutect2
- ADGRF1 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 47/558 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs1405215114; called by muse, mutect2
- ADGRV1 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.91); catalogued as rs1235225431, COSV67982419; called by muse, mutect2
- ADNP2 | c.2729C>T p.S910F | Missense Mutation (SNP) | VAF 52/448 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs760529865; called by muse, mutect2, varscan2
- AHCTF1 | c.5180C>T p.S1727F (on ENST00000366508; = p.S1701F on NM_015446.5) | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs747275720; called by muse, mutect2
- AHNAK2 | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 58/575 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.171); catalogued as rs1285636325; called by muse, mutect2, varscan2
- AKAP3 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1345037350, COSV57420026; called by muse, mutect2
- ALG10 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs765891801; called by muse, mutect2, varscan2
- ALPK2 | c.6139G>A p.E2047K | Missense Mutation (SNP) | VAF 44/430 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs776201287; called by muse, mutect2, varscan2
- ALPK2 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 64/480 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV64493930; called by muse, mutect2
- AMER1 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 71/600 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100365868; called by muse, mutect2, varscan2
- AMER3 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 62/536 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV58466791; called by muse, varscan2
- AMER3 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 55/490 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.207); catalogued as rs139544644; called by muse, mutect2, varscan2
- ANK3 | c.9892C>T p.P3298S | Missense Mutation (SNP) | VAF 51/445 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs570562727, COSV55075436; called by muse, mutect2, varscan2
- ANKRD18A | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 35/441 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68804597; called by muse, mutect2
- ANKRD2 | c.429C>T p.I143= | Splice Region (SNP) | VAF 38/432 reads (9%) | catalogued as COSV53967782; called by muse, mutect2
- ANKRD30A | c.1510C>T p.Q504* (on ENST00000611781; = p.Q448* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 17/192 reads (9%) | catalogued as COSV64624061; called by muse, mutect2
- ANKRD30A | c.1952C>T p.S651F (on ENST00000611781; = p.S595F on NM_052997.2) | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1339555665, COSV64624153; called by muse, mutect2
- ANKRD31 | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 46/493 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as COSV57163407; called by muse, mutect2
- ANKRD31 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1448134576, COSV104387301; called by muse, mutect2, varscan2
- ANKS3 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 90/586 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs769824676; called by muse, mutect2, varscan2
- ANO2 | c.712C>T p.P238S (on ENST00000356134 / NM_001278597.3; = p.P242S on NM_001278596.3) | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV59024211; called by muse, varscan2
- ANPEP | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.23); catalogued as rs774559825, COSV55589577; called by muse, mutect2, varscan2
- APOB | c.5833G>A p.D1945N | Missense Mutation (SNP) | VAF 43/399 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51929211; called by muse, mutect2, varscan2
- APOB | c.5689C>T p.R1897C | Missense Mutation (SNP) | VAF 57/352 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs189341276; called by muse, mutect2, varscan2
- APOB | c.5046G>A p.M1682I | Missense Mutation (SNP) | VAF 62/497 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs749179396, COSV51946189; called by muse, mutect2, varscan2
- ARHGAP10 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as rs201271675; called by muse, mutect2, varscan2
- ARHGAP29 | c.3589G>A p.D1197N | Missense Mutation (SNP) | VAF 57/426 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs964179875; called by muse, mutect2, varscan2
- ARHGAP35 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 96/433 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68329736; called by muse, mutect2, varscan2
- ARHGAP42 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0.089); catalogued as COSV53976424; called by muse, mutect2
- ARHGAP42 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.159); catalogued as rs1364585061; called by muse, mutect2
- ARHGAP6 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 51/376 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs1569233984, COSV57294006; called by muse, mutect2, varscan2
- ARHGDIB | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 56/365 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56762315; called by muse, mutect2, varscan2
- ARHGEF12 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 37/378 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV63104840; called by muse, mutect2
- ARHGEF35 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs1364676967; called by mutect2, varscan2
- ARMC12 | c.922C>T p.Q308* (on ENST00000373866 / NM_001286574.2; = p.Q335* on NM_145028.5) | Nonsense Mutation (SNP) | VAF 38/470 reads (8%) | catalogued as COSV55361235; called by muse, mutect2
- ARMH1 | c.918C>T p.I306= | Splice Region (SNP) | VAF 55/425 reads (13%) | catalogued as rs1192306757; called by muse, mutect2, varscan2
- ARSF | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV100839454; called by muse, mutect2, varscan2
- ARVCF | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 62/582 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1490514318; called by muse, mutect2
- ASAH1 | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148105771; called by muse, mutect2, varscan2
- ASB15 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 45/336 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs780822240; called by muse, mutect2, varscan2
- ASB4 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV57509018; called by muse, mutect2, varscan2
- ASTN2 | c.3421C>T p.R1141* (on ENST00000313400 / NM_001365069.1; = p.R1090* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 41/369 reads (11%) | catalogued as rs755917557, COSV56000013; called by muse, mutect2, varscan2
- ASXL3 | c.5124G>A p.M1708I | Missense Mutation (SNP) | VAF 60/450 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV52458941; called by muse, mutect2
- ATG9B | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 52/483 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.235); catalogued as rs915961741; called by muse, mutect2, varscan2
- ATP2B3 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 38/457 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781959495, COSV54848283; called by muse, mutect2
- ATP6V0A4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs1232526730; called by muse, mutect2, varscan2
- ATP6V0D2 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99571299; called by muse, mutect2, varscan2
- ATXN3L | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 52/525 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.296); catalogued as rs1242134104; called by muse, mutect2, varscan2
- AZGP1 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 47/351 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as COSV52798890; called by muse, mutect2, varscan2
- BBS5 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs1559126732; called by muse, mutect2, varscan2
- BCLAF3 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 58/432 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs778066860, COSV61414864; called by muse, mutect2, varscan2
- BCO2 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760923340; called by muse, mutect2, varscan2
- BCORL1 | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 83/625 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771837364; called by muse, mutect2, varscan2
- BHMT2 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 54/488 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54874616; called by muse, mutect2, varscan2
- BICD1 | c.2648T>C p.V883A | Missense Mutation (SNP) | VAF 60/453 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1205545202; called by muse, mutect2, varscan2
- BICDL2 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs746922361, COSV66370266; called by muse, mutect2, varscan2
- BMP1 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs555486532; called by muse, mutect2, varscan2
- BNC1 | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 59/512 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as rs141711507; called by muse, mutect2, varscan2
- BPIFB1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 44/316 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53608700; called by muse, mutect2, varscan2
- BRF2 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 61/445 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV55103364; called by muse, mutect2, varscan2
- BRINP2 | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 42/496 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV64176776; called by muse, mutect2
- C10orf120 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 44/375 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as COSV61492912; called by muse, varscan2
- C12orf40 | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61132911; called by muse, mutect2, varscan2
- C12orf40 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV61129266; called by muse, mutect2, varscan2
- C14orf39 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 22/232 reads (9%) | catalogued as rs754275662, COSV58783614; called by muse, mutect2
- C16orf78 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV54555053; called by muse, mutect2, varscan2
- C19orf44 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 62/485 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as COSV54172305; called by muse, mutect2, varscan2
- C1QTNF9B | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 40/685 reads (6%) | catalogued as rs749779965; called by muse, mutect2
- C4BPA | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 110/411 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65537120; called by muse, mutect2, varscan2
- C5orf52 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 65/322 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779555624, COSV69625841, COSV69626479; called by muse, mutect2, varscan2
- CACNA1E | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164365969, COSV100703927; called by muse, mutect2, varscan2
- CACNA1E | c.5680-1G>A p.X1894_splice | Splice Site (SNP) | VAF 36/404 reads (9%) | catalogued as COSV62410312; called by muse, mutect2
- CACNA1E | c.6236G>A p.G2079E (on ENST00000367573 / NM_001205293.3; = p.G2036E on NM_000721.4) | Missense Mutation (SNP) | VAF 93/376 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.527); catalogued as rs765358070, COSV62409331; called by muse, mutect2, varscan2
- CACNA1G | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 84/415 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1238555542; called by muse, mutect2, varscan2
- CACNA1I | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV60804896; called by muse, mutect2, varscan2
- CACNA2D1 | c.2195G>A p.R732Q (on ENST00000356253 / NM_001366867.1; = p.R720Q on NM_000722.4) | Missense Mutation (SNP) | VAF 28/373 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs79127167, COSV62372664; called by muse, mutect2
- CACNA2D3 | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.313); catalogued as rs1418116779; called by muse, mutect2, varscan2
- CADM4 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 98/358 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); catalogued as COSV55928573; called by muse, mutect2, varscan2
- CALCRL | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs200051216; called by muse, mutect2, varscan2
- CALCRL | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149634296; called by muse, mutect2, varscan2
- CAMK2D | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 23/304 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as COSV56439045; called by muse, mutect2
- CAPRIN1 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 47/382 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs766532737, COSV58222356; called by muse, mutect2, varscan2
- CARMIL3 | c.3586G>A p.D1196N | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs770898604, COSV57728076; called by muse, mutect2, varscan2
- CASR | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56137519; called by muse, mutect2
- CASS4 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV100824643; called by muse, mutect2, varscan2
- CATSPERD | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776962512, COSV101062331; called by muse, mutect2, varscan2
- CCDC112 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs1182512019, COSV65473059, COSV65473899; called by muse, mutect2, varscan2
- CCDC7 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.698); catalogued as COSV53229531; called by muse, mutect2, varscan2
- CCN5 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 54/485 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs748506435; called by muse, mutect2, varscan2
- CCR5 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 45/399 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs764318467, COSV52750993; called by muse, mutect2, varscan2
- CCT8L2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 56/498 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV63462408; called by muse, mutect2, varscan2
- CD28 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.853); catalogued as rs200232329; called by muse, mutect2, varscan2
- CD300A | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as COSV100177958; called by muse, mutect2, varscan2
- CD36 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.529); catalogued as rs769390260; called by muse, mutect2
- CDCP1 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 35/351 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as rs201301385; called by muse, mutect2, varscan2
- CDH4 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 49/432 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV64678377; called by muse, mutect2, varscan2
- CDH6 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 78/368 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54078289; called by muse, mutect2, varscan2
- CDH8 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54867323; called by muse, mutect2, varscan2
- CDH9 | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 72/369 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV50261146, COSV50291743; called by muse, mutect2, varscan2
- CDKL5 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 41/382 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as rs372629988, COSV66110166; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEACAM20 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 81/335 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs761041865; called by muse, mutect2, varscan2
- CELSR3 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 44/379 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs745817956; called by muse, mutect2, varscan2
- CEMIP | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 33/280 reads (12%) | catalogued as rs771721238; called by muse, mutect2, varscan2
- CENPF | c.1510C>T p.H504Y | Missense Mutation (SNP) | VAF 46/646 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV65276468; called by muse, mutect2
- CEP290 | c.4864C>T p.R1622C | Missense Mutation (SNP) | VAF 53/394 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs746576984, COSV58352317; called by muse, mutect2, varscan2
- CERKL | c.1027C>T p.R343C (on ENST00000339098 / NM_001030311.2; = p.R317C on NM_201548.5) | Missense Mutation (SNP) | VAF 55/462 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs142530341, COSV100182962; called by muse, mutect2, varscan2
- CFAP206 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51533382; called by muse, mutect2
- CFAP47 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52884843, COSV52891359; called by muse, mutect2, varscan2
- CFAP47 | c.2632C>T p.R878C | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV52881110; called by muse, mutect2, varscan2
- CFAP47 | c.5362G>A p.D1788N | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57972997, COSV57976903; called by muse, varscan2
- CFAP57 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV65264452; called by muse, mutect2, varscan2
- CFAP61 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs371793125, COSV55639118; called by muse, mutect2, varscan2
- CFH | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62777227, COSV62778910; called by muse, mutect2
- CFHR4 | c.283G>A p.E95K (on ENST00000367416 / NM_001201551.2; = p.E96K on NM_001201550.3) | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.715); catalogued as rs770331706, COSV99261264; called by muse, mutect2, varscan2
- CHAF1A | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 46/431 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs759220552; called by muse, mutect2, varscan2
- CHRNA6 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 36/479 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52380554, COSV99373250; called by muse, mutect2
- CHRNB4 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 47/435 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs867376645, COSV55714899; called by muse, mutect2, varscan2
- CLEC2L | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 59/397 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.345); catalogued as rs1450191408, COSV101406072; called by muse, mutect2, varscan2
- CLGN | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as rs1409799649, COSV57774789; called by muse, mutect2, varscan2
- CLVS1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 44/478 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs143211270, COSV57975512, COSV99073593; called by muse, mutect2
- CNGA3 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 46/393 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV55623733; called by muse, mutect2, varscan2
- CNGB3 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 48/389 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs772140410, COSV60687848; called by muse, mutect2, varscan2
- CNKSR2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs1440019745, COSV54251896; called by muse, mutect2
- CNST | c.1897C>T p.H633Y | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs559488339; called by muse, mutect2, varscan2
- CNTN4 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68586587; called by muse, mutect2, varscan2
- CNTNAP1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV52848213; called by muse, mutect2
- CNTNAP5 | c.3229C>T p.R1077C | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1360384371, COSV70497656; called by muse, mutect2, varscan2
- CNTRL | c.3590C>T p.S1197L | Missense Mutation (SNP) | VAF 46/396 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as rs1330301673, COSV99440746; called by muse, mutect2, varscan2
- COL14A1 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.594); catalogued as rs758986469, COSV52849911; called by muse, mutect2
- COL14A1 | c.4385G>A p.G1462E | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563726070; called by muse, mutect2, varscan2
- COL14A1 | c.5368G>A p.E1790K | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs776652145, COSV52866823; called by muse, mutect2, varscan2
- COL17A1 | c.2246G>A p.G749E | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866260753; called by muse, mutect2, varscan2
- COL21A1 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55152222; called by muse, mutect2, varscan2
- COL21A1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV55157270; called by muse, mutect2, varscan2
- COL27A1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs923761760; called by muse, mutect2, varscan2
- COL27A1 | c.4520G>A p.R1507Q | Missense Mutation (SNP) | VAF 54/441 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769947565; called by muse, mutect2, varscan2
- COL4A4 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796418, CM1414118; ClinVar: uncertain significance; called by muse, varscan2
- COL5A2 | c.2006G>A p.G669E | Missense Mutation (SNP) | VAF 41/324 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104425978; called by muse, mutect2, varscan2
- COL6A2 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 52/507 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1216448596; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 53/413 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs398124120, COSV55100996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 48/417 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1408694323; called by muse, mutect2, varscan2
- COL9A1 | c.1468G>A p.G490S | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV57879794; called by muse, mutect2, varscan2
- COLGALT1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as rs1200229778; called by muse, mutect2
- COQ10A | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 49/506 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs1266331688; called by muse, mutect2
- CPZ | c.703G>A p.E235K (on ENST00000360986 / NM_001014447.3; = p.E224K on NM_003652.3) | Missense Mutation (SNP) | VAF 74/428 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.442); catalogued as rs1411209507; called by muse, mutect2
- CR1 | c.3437G>A p.G1146E | Missense Mutation (SNP) | VAF 48/684 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1158666652; called by muse, mutect2
- CRAMP1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 47/400 reads (12%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.003); catalogued as rs1001291682; called by muse, mutect2, varscan2
- CRB1 | c.2735C>T p.S912F | Missense Mutation (SNP) | VAF 65/503 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV66328486; called by muse, mutect2, varscan2
- CRISP1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV59994917; called by muse, mutect2
- CSAG1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 45/402 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs1556830762, COSV63401271; called by muse, varscan2
- CSMD1 | c.9283G>A p.A3095T (on ENST00000520002; = p.A3094T on NM_033225.6) | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100152783, COSV59303561; called by muse, mutect2, varscan2
- CSMD1 | c.5311G>A p.G1771R (on ENST00000520002; = p.G1770R on NM_033225.6) | Missense Mutation (SNP) | VAF 55/388 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1305255279, COSV59383282; called by muse, mutect2, varscan2
- CSMD1 | c.4541C>T p.S1514F (on ENST00000520002; = p.S1513F on NM_033225.6) | Missense Mutation (SNP) | VAF 45/359 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59290770; called by muse, mutect2, varscan2
- CSMD2 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs756930638; called by muse, varscan2
- CST4 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 55/441 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs760057501; called by muse, mutect2, varscan2
- CTPS2 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs770159997; called by muse, mutect2, varscan2
- CUL4B | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 58/510 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100341087; called by muse, mutect2, varscan2
- CYP2C19 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs1178615892, COSV64908387; called by muse, mutect2, varscan2
- CYP4B1 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 55/407 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV54723115, COSV99596965; called by muse, mutect2, varscan2
- CYP4F2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs750923758; called by muse, mutect2, varscan2
- CYP4F8 | c.1102A>G p.K368E | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779033704; called by muse, mutect2, varscan2
- CYP4Z1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.033); catalogued as rs267598629; called by muse, mutect2, varscan2
- DAB1 | c.1348G>A p.D450N (on ENST00000371231; = p.D417N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/452 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); catalogued as COSV64690418; called by muse, mutect2, varscan2
- DAB1 | c.1201C>T p.P401S (on ENST00000371231; = p.P368S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/421 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); catalogued as COSV64695094; called by muse, mutect2, varscan2
- DCAF6 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 40/400 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776926593, COSV56585113; called by muse, mutect2
- DCC | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV59086294; called by muse, mutect2, varscan2
- DCC | c.3422G>A p.R1141K | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.688); catalogued as rs1303874568, COSV71428013; called by muse, mutect2
- DCC | c.4175C>T p.S1392F | Missense Mutation (SNP) | VAF 44/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1208410804; called by muse, mutect2
- DCDC1 | c.4423G>A p.E1475K (on ENST00000597505 / NM_001367979.1; = p.E582K on NM_020869.3) | Missense Mutation (SNP) | VAF 45/366 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1277193493, COSV58001890; called by muse, mutect2, varscan2
- DCDC1 | c.2090C>T p.P697L | Missense Mutation (SNP) | VAF 27/352 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1432100765, COSV60855795, COSV60864749; called by muse, mutect2
- DEFB116 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV68722228; called by muse, mutect2, varscan2
- DENND2A | c.1245+1G>A p.X415_splice | Splice Site (SNP) | VAF 35/263 reads (13%) | catalogued as rs1007239590; called by muse, mutect2, varscan2
- DENND4B | c.2795C>T p.S932F | Missense Mutation (SNP) | VAF 45/441 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as rs866964549; called by muse, mutect2, varscan2
- DIAPH2 | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 63/498 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV61258951; called by muse, mutect2, varscan2
- DLG2 | c.358C>T p.Q120* (on ENST00000650630 / NM_001351274.2; = p.Q83* on NM_001142699.3) | Nonsense Mutation (SNP) | VAF 28/272 reads (10%) | catalogued as COSV65840113; called by muse, mutect2, varscan2
- DMBT1 | c.7066G>A p.D2356N (on ENST00000338354 / NM_001377530.1; = p.D1599N on NM_004406.3) | Missense Mutation (SNP) | VAF 52/411 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs369691816; called by muse, mutect2, varscan2
- DNAH11 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs562163349, COSV60940098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH11 | c.4450C>T p.P1484S | Missense Mutation (SNP) | VAF 40/323 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.248); catalogued as rs769397725; called by muse, mutect2, varscan2
- DNAH3 | c.9709G>A p.E3237K | Missense Mutation (SNP) | VAF 37/500 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV54512537; called by muse, mutect2
- DNAH5 | c.9634G>A p.E3212K | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99453602; called by muse, mutect2, varscan2
- DNAH5 | c.5089G>A p.E1697K | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54201305; called by muse, mutect2, varscan2
- DNAH5 | c.1642C>T p.H548Y | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs778487272, COSV54245951; called by muse, mutect2, varscan2
- DNAH5 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV54221745; called by muse, mutect2, varscan2
- DNAH6 | c.9743G>A p.G3248E | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52876176; called by muse, mutect2, varscan2
- DNAH7 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV56771723; called by muse, mutect2, varscan2
- DNAH8 | c.3110C>T p.S1037L | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV59433818, COSV59478265; called by muse, mutect2, varscan2
- DNAH8 | c.6094G>A p.G2032R | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179035059, COSV100544970; called by muse, mutect2, varscan2
- DNAJB4 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66131996; called by muse, mutect2
- DNM3 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs774817889, COSV62462719; called by muse, mutect2, varscan2
- DNMT1 | c.960G>A p.K320= | Splice Region (SNP) | VAF 29/222 reads (13%) | catalogued as rs750048459; called by muse, mutect2, varscan2
- DOCK11 | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 53/412 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs779565571; called by muse, mutect2, varscan2
- DOCK3 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs867764185, COSV56549788; called by muse, mutect2, varscan2
- DOCK3 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56529199; called by muse, mutect2, varscan2
- DOK5 | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1273796910; called by muse, mutect2, varscan2
- DPP6 | c.885G>A p.E295= (on ENST00000377770 / NM_001364500.2; = p.E233= on NM_001936.5) | Splice Region (SNP) | VAF 23/206 reads (11%) | catalogued as rs962716654; called by muse, mutect2, varscan2
- DPYSL4 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 52/520 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1224502349; called by muse, mutect2
- DSC2 | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 42/438 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs757253682, COSV51870668; called by muse, mutect2
- DSCAM | c.4880G>A p.R1627K | Missense Mutation (SNP) | VAF 46/295 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV68029348; called by muse, mutect2, varscan2
- DSCAM | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs267606128, COSV68029375; called by muse, varscan2
- DSCAM | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV101260774; called by muse, mutect2, varscan2
- DSPP | c.2605G>A p.D869N | Missense Mutation (SNP) | VAF 71/583 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs747998467; called by muse, mutect2, varscan2
- DTX1 | c.1461G>A p.M487I | Missense Mutation (SNP) | VAF 59/578 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV55655217; called by muse, mutect2
- DTX3 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 58/524 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs542699703, COSV54085850; called by muse, mutect2, varscan2
- DUSP22 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 32/588 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.129); catalogued as COSV60528571; called by muse, mutect2
- DYDC2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 45/360 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as COSV55473310; called by muse, mutect2, varscan2
- DYSF | c.4478C>T p.S1493F | Missense Mutation (SNP) | VAF 41/367 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.254); catalogued as COSV50313610; called by muse, mutect2, varscan2
- DYTN | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs754837921; called by muse, mutect2, varscan2
- EBF3 | c.1595C>T p.S532L | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs749702381; called by muse, mutect2
- EFHD2 | c.459C>T p.F153= | Splice Region (SNP) | VAF 34/423 reads (8%) | catalogued as COSV65657889; called by muse, mutect2
- EGFLAM | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as COSV59297870; called by muse, mutect2
- EGR2 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 52/481 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs779781939; called by muse, mutect2, varscan2
- ELAPOR1 | c.1325A>G p.N442S | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs575396273; called by muse, mutect2, varscan2
- ENPEP | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 40/330 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV104371909, COSV54447414; called by muse, mutect2, varscan2
- ENPP6 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs759799702, COSV57070546; called by muse, mutect2, varscan2
- EPB41L2 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs267600809; called by muse, mutect2
- EPHA7 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 47/421 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1256527658, COSV65191152, COSV65194854; called by muse, mutect2, varscan2
- EPHA8 | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV51272873; called by muse, mutect2, varscan2
- EPHA8 | c.2735C>T p.P912L | Missense Mutation (SNP) | VAF 54/423 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs748668673; called by muse, mutect2, varscan2
- ERICH3 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 57/430 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs748851440; called by muse, mutect2, varscan2
- ERICH6 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 45/433 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373884223; called by muse, mutect2, varscan2
- ETS1 | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV67007793; called by muse, mutect2, varscan2
- F2RL1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 70/554 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.065); catalogued as COSV56997084; called by muse, mutect2, varscan2
- F8 | c.5930T>C p.F1977S | Missense Mutation (SNP) | VAF 43/397 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD1313593; called by muse, varscan2
- F8 | c.5144G>A p.R1715Q | Missense Mutation (SNP) | VAF 55/503 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs781876217, CM057443, CM067378, COSV64271324; called by muse, mutect2, varscan2
- FABP6 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 83/374 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as rs1042478773, COSV67436798; called by muse, mutect2, varscan2
- FAM135A | c.3467C>T p.P1156L (on ENST00000370479 / NM_001351599.1; = p.P943L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs534833258; called by muse, mutect2, varscan2
- FAM181A | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 57/466 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1466558185, COSV99967956; called by muse, mutect2, varscan2
- FAM186A | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 69/379 reads (18%) | catalogued as rs541010309, COSV59256231; called by muse, mutect2, varscan2
- FAM205A | c.3297G>A p.W1099* | Nonsense Mutation (SNP) | VAF 51/413 reads (12%) | catalogued as COSV101113058; called by muse, mutect2, varscan2
- FAM217A | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99212707; called by muse, mutect2
- FAM234B | c.932T>C p.V311A | Missense Mutation (SNP) | VAF 58/443 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs748162017; called by muse, mutect2, varscan2
- FAM47A | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 58/475 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV60494452; called by muse, mutect2, varscan2
- FAM83A | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 62/503 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs776658008, COSV99414437; called by muse, mutect2, varscan2
- FAM83B | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209803420; called by muse, mutect2, varscan2
- FAM83B | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 56/409 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV60926747; called by muse, mutect2, varscan2
- FAT1 | c.10145C>T p.S3382L | Missense Mutation (SNP) | VAF 56/409 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs778500047, COSV71675108; called by muse, mutect2, varscan2
- FAT1 | c.6494C>T p.S2165L | Missense Mutation (SNP) | VAF 37/367 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV71675698; called by muse, mutect2, varscan2
- FBF1 | c.2483C>T p.A828V (on ENST00000586717; = p.A842V on NM_001319193.1) | Missense Mutation (SNP) | VAF 63/329 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs775799012; called by muse, mutect2, varscan2
- FCRL3 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 106/556 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148588983; called by muse, mutect2, varscan2
- FCRL5 | c.2749C>T p.P917S | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs1285899316; called by muse, mutect2, varscan2
- FGF10 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.253); catalogued as rs1418284908; called by muse, mutect2, varscan2
- FHL5 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.055); catalogued as rs779430990, COSV58737609; called by muse, mutect2
- FIZ1 | c.297C>T p.V99= | Splice Region (SNP) | VAF 81/281 reads (29%) | catalogued as rs1273489172; called by muse, mutect2, varscan2
- FLG | c.10028G>A p.S3343N | Missense Mutation (SNP) | VAF 64/722 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs754551146, COSV64240444; called by muse, mutect2
- FLG | c.9707C>T p.S3236F | Missense Mutation (SNP) | VAF 65/598 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs532804294, COSV64244053; called by muse, varscan2
- FLG | c.7319G>A p.G2440E | Missense Mutation (SNP) | VAF 135/750 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs555272052, COSV100911233; called by muse, mutect2, varscan2
- FLG | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 89/463 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs772107622, COSV100911996, COSV100912622; called by muse, mutect2, varscan2
- FLG2 | c.6553G>A p.D2185N | Missense Mutation (SNP) | VAF 50/629 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs139340086, COSV66174542; called by muse, mutect2
- FLG2 | c.4262G>A p.G1421E | Missense Mutation (SNP) | VAF 67/701 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV66167618, COSV66170289; called by muse, mutect2
- FLG2 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 170/611 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs772274448, COSV66166946; called by muse, mutect2, varscan2
- FLNB | c.1631G>A p.G544D | Missense Mutation (SNP) | VAF 58/375 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs760794234; called by muse, mutect2, varscan2
- FLT4 | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 120/478 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs781063816, COSV56101161; called by muse, mutect2, varscan2
- FMO1 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 65/419 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61445257; called by muse, mutect2, varscan2
- FMO2 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371141652; called by muse, mutect2, varscan2
- FNDC1 | c.3650G>A p.G1217E | Missense Mutation (SNP) | VAF 59/477 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs1396162019; called by muse, mutect2, varscan2
- FOSB | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 94/387 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs754164038; called by muse, mutect2, varscan2
- FOXR2 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 73/580 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs374320995, COSV59259546; called by muse, mutect2, varscan2
- FREM1 | c.6139G>A p.D2047N | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as rs570797431, CD131585, COSV101085707; called by muse, varscan2
- FREM3 | c.4119G>A p.M1373I | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV61679338; called by muse, mutect2, varscan2
- FRMD1 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.683); catalogued as rs1174210990; called by muse, mutect2, varscan2
- FSIP1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 41/372 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as COSV63225314, COSV63226390; called by muse, mutect2, varscan2
- FSTL5 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1460631176; called by muse, mutect2, varscan2
- FUT9 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 38/329 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs866379874, COSV56144259; called by muse, varscan2
- FUT9 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs868515812, COSV100133533, COSV104402639, COSV56144749; called by muse, varscan2
- GABBR1 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 47/471 reads (10%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.67); catalogued as COSV100589899; called by muse, mutect2
- GABBR2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 41/456 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1021777878, COSV52299650; called by muse, mutect2
- GABRB3 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 61/432 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV54674896; called by muse, mutect2, varscan2
- GABRQ | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 54/416 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.552); catalogued as rs1556817722; called by muse, mutect2, varscan2
- GALNT13 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.068); catalogued as COSV67222340; called by muse, mutect2, varscan2
- GALNT16 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1331191426; called by muse, mutect2
- GALNT17 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 41/391 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs761319548, COSV61149532, COSV61173595; called by muse, mutect2, varscan2
- GALNT17 | c.1696G>A p.G566R | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV61150825; called by muse, mutect2, varscan2
- GAP43 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 60/474 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs267599554; called by muse, mutect2, varscan2
- GBP2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1402255824; called by muse, mutect2, varscan2
- GDF5 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 55/415 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs766838573, COSV65499834, COSV65503910; called by muse, varscan2
- GDF9 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 115/529 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs367679901; called by muse, mutect2, varscan2
- GGA1 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 50/389 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs141488222, COSV100289829; called by muse, mutect2, varscan2
- GGCX | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 28/275 reads (10%) | catalogued as rs755908721; called by muse, mutect2, varscan2
- GGT5 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 60/440 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1419126653; called by muse, mutect2, varscan2
- GHR | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 57/269 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs542317809, COSV50115273; called by muse, mutect2, varscan2
- GJD4 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 61/554 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1327691412; called by muse, mutect2, varscan2
- GK3P | c.1116G>A p.W372* | Nonsense Mutation (SNP) | VAF 54/483 reads (11%) | catalogued as rs756829282; called by muse, mutect2, varscan2
- GLRA3 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771115012, COSV56857256; called by muse, mutect2, varscan2
- GLYAT | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1395774688, COSV53539994; called by muse, mutect2, varscan2
- GLYATL2 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.662); catalogued as rs372043704; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 76/996 reads (8%) | SIFT tolerated, low confidence (0.81); catalogued as rs1423977699; called by muse, mutect2
- GOLGA6L7 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 27/444 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.38); catalogued as rs763513868, COSV101629716; called by muse, mutect2
- GPC2 | c.1685C>T p.T562I | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.351); catalogued as rs1170634694; called by muse, mutect2
- GPC4 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 46/435 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.188); catalogued as rs1420788652; called by muse, mutect2, varscan2
- GPR31 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 54/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs771966134; called by muse, mutect2, varscan2
- GPR50 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 75/588 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV54440019; called by muse, mutect2, varscan2
- GPX5 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs773612149, COSV101297251; called by muse, mutect2, varscan2
- GRHL1 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 13/237 reads (5%) | catalogued as COSV61409148; called by muse, mutect2
- GRIA3 | c.2571G>A p.M857I | Missense Mutation (SNP) | VAF 50/396 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52072474; called by muse, mutect2, varscan2
- GRID1 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 68/567 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs770555419, COSV60049348; called by muse, mutect2, varscan2
- GRIN3A | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 40/348 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs867585563, COSV62457494; called by muse, mutect2, varscan2
- GRIN3A | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs866020232; called by muse, mutect2, varscan2
- GRM3 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 50/474 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64473539; called by muse, varscan2
- GRM3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 56/428 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.216); catalogued as COSV64466918; called by muse, varscan2
- GRP | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 47/402 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs200302824; called by muse, varscan2
- GSTCD | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100853824; called by muse, mutect2, varscan2
- GTF3C1 | c.2666dup p.I892Nfs*98 | Frame Shift Ins (INS) | VAF 40/402 reads (10%) | catalogued as COSV100649390; called by mutect2, pindel, varscan2
- H1-7 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 59/561 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs1354541232, COSV58602591; called by muse, mutect2, varscan2
- H3-5 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 56/502 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as rs1175067252, COSV61187172; called by muse, mutect2, varscan2
- HAUS7 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 60/579 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.137); catalogued as rs1387457323; called by muse, mutect2, varscan2
- HBS1L | c.1139T>A p.F380Y | Missense Mutation (SNP) | VAF 52/441 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV63201643; called by muse, mutect2, varscan2
- HCFC1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV60070202; called by muse, varscan2
- HCK | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs372761182; called by muse, mutect2
- HCLS1 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs142545513; called by muse, mutect2, varscan2
- HCN1 | c.2371C>T p.P791S | Missense Mutation (SNP) | VAF 111/588 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as rs752908921; called by muse, mutect2, varscan2
- HDAC9 | c.2707G>A p.D903N | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV101286630; called by muse, mutect2, varscan2
- HEPH | c.1729G>A p.E577K (on ENST00000343002; = p.E310K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57960943; called by muse, mutect2, varscan2
- HERC2 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 59/515 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs201542966, COSV55321457; called by muse, mutect2, varscan2
- HHIP | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56839939, COSV56840502; called by muse, varscan2
- HNF1B | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 143/592 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as CM055549; called by muse, mutect2, varscan2
- HNRNPCL2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 56/555 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs772029086; called by muse, varscan2
- HOXA10 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 59/469 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52228865; called by muse, mutect2, varscan2
- HRNR | c.1880G>A p.G627E | Missense Mutation (SNP) | VAF 223/1108 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.949); catalogued as rs776098019; called by muse, mutect2, varscan2
- HS3ST5 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 50/448 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV57139875; called by muse, mutect2, varscan2
- HS6ST2 | c.922C>A p.R308S | Missense Mutation (SNP) | VAF 52/391 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV63711362; called by muse, mutect2, varscan2
- HSD3B2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as CM1414273, COSV65593771; called by muse, mutect2, varscan2
- HTR3B | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 39/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs766597002; called by muse, mutect2, varscan2
- HYDIN | c.13666G>A p.D4556N | Missense Mutation (SNP) | VAF 27/338 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs777444703; called by muse, mutect2
- HYDIN | c.5171C>T p.S1724F | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1187007901, COSV59261736; called by muse, mutect2
- HYDIN | c.4930C>T p.R1644C | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs993703682, COSV59255296; called by muse, mutect2, varscan2
- IDE | c.597G>A p.W199* | Nonsense Mutation (SNP) | VAF 46/368 reads (13%) | catalogued as COSV99793975; called by muse, mutect2, varscan2
- IFNA16 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 51/399 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV66510432; called by muse, mutect2, varscan2
- IGSF1 | c.3169G>A p.E1057K | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV63838134; called by muse, mutect2, varscan2
- IKZF3 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754805856, COSV53104022; called by muse, mutect2, varscan2
- IL13RA2 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV54563961; called by muse, mutect2, varscan2
- IL31RA | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as rs748412872, COSV51680267; called by muse, mutect2, varscan2
- ILDR1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV99878468; called by muse, mutect2, varscan2
- INAVA | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 119/477 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.314); catalogued as rs1348939505; called by muse, mutect2, varscan2
- INPP5D | c.1885G>A p.V629I (on ENST00000445964 / NM_001017915.3; = p.V628I on NM_005541.5) | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs371795790; called by muse, mutect2
- INSL6 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 53/369 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs757105790, COSV67563043; called by muse, mutect2, varscan2
- INSYN2B | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 84/432 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as COSV99916101; called by muse, mutect2, varscan2
- INTS1 | c.6110C>T p.S2037F | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1247604788; called by muse, mutect2, varscan2
- INTS6L | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 61/643 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV66085487; called by muse, mutect2
- IQCA1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760111545, COSV54513151; called by muse, mutect2
- IQUB | c.2297G>A p.G766D | Missense Mutation (SNP) | VAF 40/464 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1479137457, COSV61243203; called by muse, mutect2
- ITGA10 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.362); catalogued as rs1468862412; called by muse, mutect2, varscan2
- ITGB3 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 151/505 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs763127353; called by muse, mutect2, varscan2
- ITPR1 | c.5439G>A p.M1813I (on ENST00000354582; = p.M1758I on NM_002222.7) | Missense Mutation (SNP) | VAF 52/532 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV56976854; called by muse, mutect2
- IZUMO2 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV53231450; called by muse, mutect2, varscan2
- KASH5 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 75/345 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.086); catalogued as COSV71358218; called by muse, mutect2, varscan2
- KCNH5 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 46/435 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs765947232, COSV59764081; called by muse, mutect2, varscan2
- KCNJ14 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 79/338 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.653); catalogued as COSV100655751; called by muse, mutect2, varscan2
- KCNK2 | c.158C>T p.T53I (on ENST00000444842 / NM_001017425.3; = p.T38I on NM_014217.4) | Missense Mutation (SNP) | VAF 84/448 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs372323312; called by muse, mutect2, varscan2
- KCNT1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 40/426 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs778405770, COSV53681862; ClinVar: uncertain significance; called by muse, mutect2
- KCNT2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 49/353 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs367968673, COSV54116241; called by muse, mutect2, varscan2
- KCNU1 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.44); catalogued as rs773221041, COSV67759076; called by muse, mutect2, varscan2
- KCNV2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 60/546 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1016081678; called by muse, mutect2, varscan2
- KIAA1522 | c.155C>T p.P52L (on ENST00000373480 / NM_001198972.2; = p.P111L on NM_020888.3) | Missense Mutation (SNP) | VAF 50/461 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1199392099; called by muse, mutect2, varscan2
- KIF26A | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 78/658 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1373974232, COSV100181580; called by muse, mutect2
- KIF26A | c.3880G>A p.A1294T | Missense Mutation (SNP) | VAF 61/657 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs991110513, COSV100181404; called by muse, mutect2
- KLHL13 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 58/393 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53245841; called by muse, mutect2, varscan2
- KLHL13 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 80/533 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV53253693; called by muse, mutect2, varscan2
- KLHL4 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 60/460 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs190477338, COSV64139169; called by muse, mutect2, varscan2
- KMT2A | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 37/351 reads (11%) | catalogued as COSV63281732; called by muse, mutect2, varscan2
- KMT2B | c.5240C>T p.S1747L | Missense Mutation (SNP) | VAF 93/340 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55859858; called by muse, mutect2, varscan2
- KMT2C | c.9229C>T p.R3077C | Missense Mutation (SNP) | VAF 41/358 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs145953124; called by muse, mutect2, varscan2
- KNDC1 | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as rs1041619421; called by muse, mutect2, varscan2
- KNOP1 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 55/455 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV54926669; called by muse, mutect2, varscan2
- KRT24 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 63/359 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV52880966; called by muse, mutect2, varscan2
- KRT31 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 151/496 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs148992540; called by muse, mutect2, varscan2
- KRT71 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as rs778601047, COSV57288926; called by muse, mutect2
- KRTAP10-7 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 90/635 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1555928846, COSV59113617; called by muse, mutect2, varscan2
- KSR2 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs754794838, COSV60386241; called by muse, mutect2, varscan2
- LCE1C | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 68/653 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); catalogued as COSV64219019; called by muse, mutect2, varscan2
- LCOR | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV63630958; called by muse, mutect2, varscan2
- LCT | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 49/484 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1305999929; called by muse, mutect2, varscan2
- LDOC1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 58/488 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.043); catalogued as rs782413542; called by muse, mutect2, varscan2
- LHPP | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 34/351 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV64331279; called by muse, mutect2, varscan2
- LHX5 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs148774477, COSV55662812; called by muse, mutect2, varscan2
- LIFR | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.312); catalogued as rs571743818; called by muse, mutect2
- LINGO3 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 93/571 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV68261909; called by muse, mutect2, varscan2
- LIPN | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1252174080, COSV101356214; called by muse, mutect2
- LMOD2 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 65/491 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV71755768; called by muse, mutect2, varscan2
- LOXHD1 | c.5003G>A p.R1668Q | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.074); catalogued as rs572531886; called by muse, mutect2, varscan2
- LRFN5 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs1051039315, COSV53243316, COSV53273551; called by muse, varscan2
- LRP1B | c.13099G>A p.G4367R | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV67269623; called by muse, mutect2, varscan2
- LRP1B | c.12700G>A p.D4234N | Missense Mutation (SNP) | VAF 48/413 reads (12%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as rs867914094, COSV67244438; called by muse, mutect2, varscan2
- LRP1B | c.7523C>T p.S2508F | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1393251553, COSV67193597; called by muse, varscan2
- LRP1B | c.1855G>A p.G619S | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV67242756; called by muse, mutect2
- LRP1B | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 47/442 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs768625188, COSV67242727; called by muse, mutect2, varscan2
- LRP2 | c.4435C>T p.R1479C | Missense Mutation (SNP) | VAF 48/359 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs760099721, COSV55574428; called by muse, mutect2, varscan2
- LRRC72 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1443345408, COSV69129276; called by muse, mutect2, varscan2
- LRRIQ1 | c.4156G>A p.E1386K | Missense Mutation (SNP) | VAF 38/399 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV67826310; called by muse, mutect2
- LUZP2 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs868695528, COSV61218956; called by muse, mutect2
- LZTS3 | c.1952C>T p.P651L (on ENST00000329152; = p.P605L on NM_001282533.2) | Missense Mutation (SNP) | VAF 60/533 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1395107584, COSV99418461; called by muse, mutect2, varscan2
- MAB21L1 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 59/448 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs146905585; called by muse, mutect2, varscan2
- MAEL | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 62/348 reads (18%) | catalogued as rs199904572, COSV63303863; called by muse, mutect2, varscan2
- MAGEB6 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 66/570 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV66871854; called by muse, varscan2
- MAGEB6 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 66/610 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as rs773473561, COSV66873048; called by muse, varscan2
- MAGEB6 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 54/640 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV66871988; called by muse, mutect2
- MAGEC2 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 56/613 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.424); catalogued as COSV55998321, COSV56002040; called by muse, mutect2
- MAGEE2 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 60/575 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV64897345; called by muse, mutect2
- MALL | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 42/723 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs764376036, COSV55599923; called by muse, mutect2
- MALRD1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV67127484; called by muse, mutect2, varscan2
- MAML1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 75/399 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.012); catalogued as rs578168072, COSV99483325; called by muse, mutect2, varscan2
- MAN1B1 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432733968; called by muse, mutect2, varscan2
- MAP3K19 | c.3018G>A p.W1006* | Nonsense Mutation (SNP) | VAF 38/418 reads (9%) | catalogued as COSV59640340; called by muse, mutect2
- MAP3K19 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV59642644; called by muse, mutect2, varscan2
- MAP9 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs767767555, COSV60904674; called by muse, mutect2
- MAPKBP1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 35/365 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV99529683; called by muse, mutect2
- MARCHF4 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56104177; called by muse, mutect2, varscan2
- MARCO | c.426G>A p.G142= | Splice Region (SNP) | VAF 40/396 reads (10%) | catalogued as COSV59054463; called by muse, varscan2
- MARCO | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59053635; called by muse, mutect2, varscan2
- MARCO | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 49/451 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304820312, COSV59056296, COSV59056478; called by muse, mutect2
- MAST4 | c.1366C>T p.R456C (on ENST00000403625 / NM_001164664.2; = p.R267C on NM_015183.3) | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55141426; called by muse, mutect2, varscan2
- MCCC2 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 118/502 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs746257649; called by muse, mutect2, varscan2
- MCTP1 | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 71/350 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as rs202198042; called by muse, mutect2, varscan2
- MCTP2 | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs187187495, COSV63292683; called by muse, mutect2, varscan2
- MDGA1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs771400570; called by muse, mutect2, varscan2
- MDGA2 | c.2446C>T p.H816Y (on ENST00000399232 / NM_001113498.2; = p.H518Y on NM_182830.4) | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.844); catalogued as COSV100636525, COSV62091648; called by muse, mutect2, varscan2
- MECOM | c.899C>T p.S300F (on ENST00000468789 / NM_001105078.4; = p.S488F on NM_004991.4) | Missense Mutation (SNP) | VAF 47/423 reads (11%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.556); catalogued as rs267599685, COSV52961844; called by muse, mutect2, varscan2
- MED14 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 61/482 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as rs764282931; called by muse, mutect2, varscan2
- MEFV | c.1895G>A p.G632D | Missense Mutation (SNP) | VAF 53/439 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.108); catalogued as CM146757; called by muse, mutect2, varscan2
- MEFV | c.1894G>A p.G632S | Missense Mutation (SNP) | VAF 52/442 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as rs104895128, CM045304, COSV54818469; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- MEFV | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 63/489 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as CM152450; called by muse, mutect2, varscan2
- MEFV | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 52/441 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV54824535; called by muse, varscan2
- MEGF9 | c.1327C>T p.H443Y | Missense Mutation (SNP) | VAF 47/369 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV64236663; called by muse, mutect2, varscan2
- MGAM | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs782295291, COSV71885410; called by muse, mutect2, varscan2
- MGAM2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1251144551; called by muse, mutect2, varscan2
- MIPEP | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as rs1391277946, COSV65944511; called by muse, mutect2, varscan2
- MKI67 | c.7753C>T p.P2585S | Missense Mutation (SNP) | VAF 51/436 reads (12%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.557); catalogued as COSV64077037; called by muse, mutect2, varscan2
- MNDA | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1161457689, COSV63741515, COSV63742101; called by muse, mutect2
- MOGS | c.1809G>A p.W603* | Nonsense Mutation (SNP) | VAF 54/430 reads (13%) | catalogued as COSV51969628; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746240316, COSV56620954; called by muse, mutect2, varscan2
- MRAP2 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 75/531 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100004649; called by muse, mutect2, varscan2
- MRC2 | c.2971C>T p.P991S | Missense Mutation (SNP) | VAF 83/397 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV100316622; called by muse, mutect2, varscan2
- MROH2A | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 44/423 reads (10%) | catalogued as COSV67682070; called by muse, mutect2, varscan2
- MROH2B | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68180822, COSV68182913; called by muse, mutect2, varscan2
- MROH2B | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 43/542 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs865973702; called by muse, mutect2
- MS4A6A | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60619161; called by muse, varscan2
- MSR1 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as rs777923385; called by muse, mutect2, varscan2
- MTMR7 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs779278498; called by muse, mutect2, varscan2
- MTMR8 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 48/396 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs962698743; called by muse, mutect2, varscan2
- MTOR | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 50/392 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV63868362; called by muse, mutect2, varscan2
- MUC16 | c.39835C>T p.L13279F | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as rs867004768; called by muse, mutect2
- MUC16 | c.30629C>T p.S10210L | Missense Mutation (SNP) | VAF 46/478 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs1409544932, COSV101198522, COSV67442346; called by muse, mutect2
- MUC16 | c.29932G>A p.A9978T | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.07); catalogued as COSV67497253; called by muse, mutect2, varscan2
- MUC16 | c.11035C>T p.R3679C | Missense Mutation (SNP) | VAF 53/419 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.276); catalogued as COSV67490095; called by muse, mutect2, varscan2
- MUC16 | c.8920G>A p.E2974K | Missense Mutation (SNP) | VAF 51/401 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67477786; called by muse, mutect2, varscan2
- MUC16 | c.8463G>A p.M2821I | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as rs267605807, COSV67472890; called by muse, mutect2, varscan2
- MUC16 | c.3620C>T p.P1207L | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as rs763693715; called by muse, varscan2
- MUC16 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs914279668, COSV67474613; called by muse, mutect2, varscan2
- MUC16 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 35/379 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as COSV67446364; called by muse, mutect2
- MUSK | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as rs754275653, COSV51891534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MXRA5 | c.8354G>A p.G2785E | Missense Mutation (SNP) | VAF 74/558 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54245037; called by muse, mutect2, varscan2
- MXRA5 | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 62/510 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV54232353; called by muse, mutect2
- MXRA5 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 67/483 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54234907; called by muse, mutect2, varscan2
- MYBPC3 | c.3205C>T p.P1069S | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs1014555110, COSV57031237; called by muse, mutect2
- MYH1 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 60/417 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs780763560, COSV56843727, COSV56851492; called by muse, mutect2, varscan2
- MYH7 | c.5190G>A p.M1730I | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV100806851; called by muse, mutect2
- MYH7 | c.4787C>T p.S1596L | Missense Mutation (SNP) | VAF 68/517 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs774540446; called by muse, mutect2, varscan2
- MYH8 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV67959790; called by muse, mutect2, varscan2
- MYL9 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 45/445 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs750083965, COSV54072366; called by muse, mutect2, varscan2
- MYO15A | c.2837G>A p.G946D | Missense Mutation (SNP) | VAF 56/339 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.55); catalogued as rs1192986169; called by muse, mutect2, varscan2
- MYO3A | c.3910G>A p.E1304K | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.265); catalogued as COSV99778429; called by muse, mutect2, varscan2
- MYO3B | c.2198C>T p.S733L | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866879141, COSV100509399, COSV58714099; called by muse, mutect2, varscan2
- NAA25 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 36/353 reads (10%) | catalogued as rs1287477535, COSV55709487; called by muse, mutect2, varscan2
- NAA30 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs1274133687; called by muse, mutect2
- NAF1 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as rs372891113; called by muse, mutect2, varscan2
- NAP1L2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 69/474 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV65172605, COSV65172728; called by muse, varscan2
- NCOR1 | c.4246G>A p.G1416R | Missense Mutation (SNP) | VAF 40/293 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV51970368; called by muse, mutect2, varscan2
- NEB | c.8803C>T p.Q2935* | Nonsense Mutation (SNP) | VAF 41/467 reads (9%) | catalogued as rs1351747266; called by muse, mutect2
- NECAP1 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 49/337 reads (15%) | catalogued as COSV100331637; called by muse, mutect2, varscan2
- NEFM | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 57/462 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.815); catalogued as rs868506885, COSV55333041; called by muse, mutect2, varscan2
- NELL1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs758492521; called by muse, mutect2, varscan2
- NEXMIF | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 76/557 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV50173998; called by muse, mutect2, varscan2
- NF1 | c.7201C>T p.P2401S (on ENST00000358273 / NM_001042492.3; = p.P2380S on NM_000267.3) | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.633); catalogued as COSV62226729; called by muse, mutect2
- NHLRC1 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 105/692 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV61481243; called by muse, mutect2, varscan2
- NIFK | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 48/388 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.159); catalogued as rs60119699; called by muse, mutect2, varscan2
- NKAPL | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 42/436 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1469449789, COSV100642599; called by muse, mutect2, varscan2
- NLRC4 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV61595262; called by muse, mutect2, varscan2
- NLRP11 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1415832467, COSV64087919; called by muse, mutect2, varscan2
- NLRP2 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs775496594; called by muse, varscan2
- NLRP2 | c.2746G>A p.D916N | Missense Mutation (SNP) | VAF 97/483 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs374020777; called by muse, mutect2, varscan2
- NLRP3 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 51/454 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs369910640; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP7 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 165/720 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1355632267, COSV60172417; called by muse, mutect2, varscan2
- NLRP8 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 95/369 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs771207728, COSV52583961; called by muse, mutect2, varscan2
- NOTCH1 | c.3707C>T p.P1236L | Missense Mutation (SNP) | VAF 65/422 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1241855040; called by muse, mutect2, varscan2
- NOTCH3 | c.4867C>T p.P1623S | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.571); catalogued as COSV54632947; called by muse, mutect2, varscan2
- NOX3 | c.1323G>A p.W441* | Nonsense Mutation (SNP) | VAF 44/346 reads (13%) | catalogued as COSV50153747; called by muse, mutect2, varscan2
- NPAP1 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 55/476 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100276382; called by muse, mutect2, varscan2
- NR3C2 | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 44/424 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.887); catalogued as COSV60986305; called by muse, mutect2
- NRDE2 | c.1650G>A p.W550* | Nonsense Mutation (SNP) | VAF 33/379 reads (9%) | catalogued as rs779791343; called by muse, mutect2
- NRG1 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 31/347 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750264919, COSV55168583; called by muse, mutect2
- NRG2 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 122/602 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs947701574, COSV56838133; called by muse, mutect2
- NRG3 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 47/375 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs764611896, COSV64545820, COSV64548799; called by muse, mutect2, varscan2
- NSUN7 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57276272; called by muse, mutect2, varscan2
- NT5C1B | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs750593394, COSV58397317; called by muse, mutect2, varscan2
- NUAK1 | c.1358A>G p.K453R | Missense Mutation (SNP) | VAF 66/363 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as rs747568443; called by muse, mutect2, varscan2
- OBSCN | c.13720G>A p.E4574K | Missense Mutation (SNP) | VAF 86/594 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.585); catalogued as rs1465573302, COSV52760069; called by muse, mutect2, varscan2
- OLAH | c.274G>A p.D92N (on ENST00000378228 / NM_001039702.3; = p.D145N on NM_018324.3) | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as rs774664197, COSV65491981; called by muse, mutect2, varscan2
- OLFML1 | c.638G>A p.W213* | Nonsense Mutation (SNP) | VAF 34/317 reads (11%) | catalogued as rs1357533526; called by muse, mutect2, varscan2
- OLFML2A | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 67/541 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs1171081862, COSV100053717; called by muse, mutect2, varscan2
- OLIG3 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 64/475 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.343); catalogued as rs765496382; called by muse, mutect2, varscan2
- OR10R2 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 68/390 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs906660981, COSV63769692; called by muse, mutect2, varscan2
- OR10R2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 126/496 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV63768558; called by muse, mutect2, varscan2
- OR10R2 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 41/489 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1319268932, COSV100936813; called by muse, mutect2
- OR10W1 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 70/465 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs369736550; called by muse, mutect2, varscan2
- OR10Z1 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 45/556 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs144307016; called by muse, mutect2
- OR13C2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 28/451 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220001507, COSV73377667; called by muse, mutect2
- OR13D1 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59515189; called by muse, mutect2, varscan2
- OR14A2 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 32/407 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV63573125; called by muse, mutect2
- OR1K1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs748623617, COSV52956973; called by muse, mutect2, varscan2
- OR1M1 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 44/429 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376976283; called by muse, mutect2, varscan2
- OR2A25 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 40/406 reads (10%) | catalogued as rs866944696, COSV68716818; called by muse, mutect2, varscan2
- OR2D2 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100203918; called by muse, mutect2, varscan2
- OR2T27 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 37/420 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as COSV61283152; called by muse, mutect2
- OR2T34 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 48/908 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs777688417; called by muse, mutect2
- OR3A1 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747437390; called by muse, mutect2, varscan2
- OR4A15 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 54/457 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs377228643, COSV59036973; called by muse, mutect2, varscan2
- OR4A47 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 52/454 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs759878805; called by muse, varscan2
- OR4A47 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.908); catalogued as rs764581468; called by muse, mutect2
- OR4A5 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 50/508 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.168); catalogued as rs1272112332, COSV60524301; called by muse, mutect2
- OR4C11 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56355100; called by muse, mutect2, varscan2
- OR4C13 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 47/369 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.421); catalogued as COSV101634249; called by muse, mutect2, varscan2
- OR4C3 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100168301; called by muse, mutect2, varscan2
- OR4E2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 52/419 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs866396121, COSV57731749; called by muse, mutect2, varscan2
- OR4K1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53463214, COSV99578940; called by muse, mutect2
- OR4K2 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1288967692, COSV53849761; called by muse, mutect2, varscan2
- OR4M1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 58/517 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV60059274; called by muse, mutect2, varscan2
- OR4Q3 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV104404868, COSV59177839, COSV99045369; called by muse, mutect2
- OR51I1 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 65/464 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV66507429; called by muse, mutect2, varscan2
- OR51M1 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 63/438 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs867064691, COSV60784583; called by muse, mutect2, varscan2
- OR52A1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs753102211, COSV61092141, COSV61093171; called by muse, mutect2, varscan2
- OR52E2 | c.156G>C p.K52N | Missense Mutation (SNP) | VAF 49/376 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58612336, COSV58612385; called by muse, mutect2, varscan2
- OR52I2 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 50/786 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs557100327, COSV100443039; called by muse, mutect2
- OR52N1 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 38/538 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57692903; called by muse, mutect2
- OR56A3 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs374842307, COSV99052017; called by muse, mutect2, varscan2
- OR5A1 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs149121720; called by muse, mutect2
- OR5AR1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1341522509; called by muse, mutect2, varscan2
- OR5H15 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.119); catalogued as rs746882832, COSV100736686, COSV62947859; called by muse, mutect2, varscan2
- OR5H6 | c.95G>A p.G32E (on ENST00000642105; = p.G16E on NM_001005479.2) | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765251519, COSV67351343; called by muse, mutect2
- OR5T1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 54/436 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs868502201, COSV57301601; called by muse, mutect2, varscan2
- OR6A2 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 48/374 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746000633; called by muse, mutect2, varscan2
- OR6B1 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 56/475 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV68769846; called by muse, mutect2, varscan2
- OR6C3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); catalogued as rs866375503, COSV65570631; called by muse, mutect2, varscan2
- OR6N2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59412231; called by muse, mutect2, varscan2
- OR6T1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 62/408 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs749592607, COSV100189714, COSV58308535; called by muse, mutect2, varscan2
- OR6Y1 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 35/357 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV100225405, COSV56930930; called by muse, mutect2, varscan2
- OR6Y1 | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 54/444 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.322); catalogued as rs1050836757; called by muse, varscan2
- OR8G1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.323); catalogued as COSV100422498; called by muse, mutect2, varscan2
- OR9K2 | c.151C>T p.L51F (on ENST00000305377; = p.L29F on NM_001005243.1) | Missense Mutation (SNP) | VAF 68/609 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV59532654; called by muse, mutect2
- ORC1 | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 36/281 reads (13%) | catalogued as rs1326632894; called by muse, mutect2, varscan2
- ORM2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 44/624 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as rs1481348194; called by muse, mutect2
- OSBP | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs764637254, COSV99803039; called by muse, mutect2, varscan2
- OSMR | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.284); catalogued as COSV57090569; called by muse, mutect2, varscan2
- OTOGL | c.5431G>A p.E1811K (on ENST00000547103; = p.E1802K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV54024787; called by muse, mutect2
- OTOGL | c.5611G>A p.D1871N (on ENST00000547103; = p.D1862N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100087092; called by muse, mutect2, varscan2
- OTUD6A | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 77/550 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57973589; called by muse, mutect2, varscan2
- OTUD7A | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1220780501, COSV100192651, COSV61036185; called by muse, mutect2, varscan2
- PACS1 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV57699641; called by muse, mutect2, varscan2
- PAFAH1B3 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1242789007; called by muse, mutect2, varscan2
- PAK5 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 46/417 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs781706438, COSV62029791; called by muse, mutect2, varscan2
- PAMR1 | c.1769C>T p.S590F (on ENST00000619888 / NM_001001991.3; = p.S607F on NM_015430.4) | Missense Mutation (SNP) | VAF 83/567 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV53514256; called by muse, mutect2, varscan2
- PAPPA2 | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 84/509 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1292493998, COSV62780292; called by muse, mutect2, varscan2
- PARP11 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs762146923, COSV57393424; called by muse, mutect2, varscan2
- PASD1 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 76/524 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV100948990; called by muse, mutect2, varscan2
- PCARE | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 43/337 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs759269733, COSV100527676, COSV59053819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH12 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 115/514 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99185749; called by muse, mutect2, varscan2
- PCDH19 | c.2857G>A p.E953K (on ENST00000373034 / NM_001184880.2; = p.E905K on NM_020766.3) | Missense Mutation (SNP) | VAF 53/371 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV55261269; called by muse, mutect2, varscan2
- PCDHA9 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 120/506 reads (24%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs781970599; called by muse, mutect2
- PCDHA9 | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 82/456 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100970042; called by muse, mutect2, varscan2
- PCDHB15 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 162/821 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs138137351; called by muse, mutect2, varscan2
- PCDHB16 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 123/522 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as COSV53367857; called by muse, mutect2, varscan2
- PCDHB7 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 98/440 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.913); catalogued as COSV99177435; called by muse, mutect2, varscan2
- PCDHB7 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 50/409 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs546236115, COSV50755630; called by muse, mutect2, varscan2
- PCDHGA4 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 49/470 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as rs759254327, COSV53907084; called by muse, mutect2, varscan2
- PCNT | c.6884C>T p.P2295L | Missense Mutation (SNP) | VAF 46/432 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs572123043; called by muse, mutect2
- PCNX1 | c.5408C>T p.A1803V | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.573); catalogued as rs959425703; called by muse, mutect2, varscan2
- PCNX2 | c.4925G>A p.G1642E | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50803250; called by muse, mutect2, varscan2
- PCNX2 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs374111803; called by muse, mutect2, varscan2
- PCSK1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 26/325 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as COSV60736693; called by muse, mutect2
- PDE4D | c.1354G>A p.E452K (on ENST00000340635 / NM_001104631.2; = p.E316K on NM_006203.4) | Missense Mutation (SNP) | VAF 85/353 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs913974941; called by muse, mutect2, varscan2
- PDE6C | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 67/510 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.2); catalogued as rs779065446; called by muse, mutect2, varscan2
- PDE9A | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs1324452006, COSV52331381; called by muse, mutect2, varscan2
- PEG3 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 119/522 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.332); catalogued as COSV55643556; called by muse, mutect2, varscan2
- PEX19 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 51/606 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs977067267, COSV63619648; called by muse, mutect2
- PFKFB1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 60/441 reads (14%) | PolyPhen probably damaging (0.993); catalogued as COSV66628432; called by muse, mutect2, varscan2
- PGD | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs562944056, COSV54620971; called by muse, mutect2, varscan2
- PGK2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 50/466 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59163049; called by muse, mutect2, varscan2
- PHF13 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 68/481 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1406240037; called by muse, mutect2, varscan2
- PHKA2 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 44/369 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1310438804; called by muse, mutect2, varscan2
- PHOX2B | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99890946; called by muse, mutect2
- PI4K2B | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 33/327 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53513180; called by muse, mutect2, varscan2
- PI4K2B | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99335688; called by muse, mutect2, varscan2
- PIEZO2 | c.4705G>A p.E1569K | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.339); catalogued as COSV57441028; called by muse, mutect2
- PKD1L2 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as rs761307275; called by muse, mutect2, varscan2
- PKHD1L1 | c.5908G>A p.G1970R | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774143522; called by muse, mutect2, varscan2
- PKP3 | c.1923G>A p.R641= | Splice Region (SNP) | VAF 35/320 reads (11%) | catalogued as rs955199381; called by muse, mutect2, varscan2
- PLAG1 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 41/391 reads (10%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.636); catalogued as COSV57609429; called by muse, mutect2, varscan2
- PLCE1 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as rs771124727, COSV53337446; called by muse, mutect2
- PLCH1 | c.3083C>T p.S1028F (on ENST00000340059 / NM_001130960.2; = p.S1020F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/385 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); catalogued as COSV58196523; called by muse, mutect2, varscan2
- PLEKHG1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370177473; called by muse, mutect2, varscan2
- PLEKHG2 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 81/349 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.637); catalogued as rs150254568; called by muse, mutect2, varscan2
- PLEKHN1 | c.743G>A p.G248E (on ENST00000379409; = p.G208E on NM_001160184.2) | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1482659247; called by muse, mutect2, varscan2
- PNLIP | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1438228056; called by muse, mutect2, varscan2
- PNPLA3 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 59/440 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs781391159; called by muse, mutect2, varscan2
- POF1B | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 42/502 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53136604; called by muse, mutect2
- POLA1 | c.4097G>A p.R1366Q | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as rs769412757, COSV100985537; called by muse, mutect2
- POLR2B | c.2575C>T p.R859C | Missense Mutation (SNP) | VAF 52/401 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1297561834; called by muse, mutect2, varscan2
- POM121L12 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 65/584 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs1237978448; called by muse, mutect2, varscan2
- POTEF | c.3143C>T p.S1048L | Missense Mutation (SNP) | VAF 40/562 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as rs1389528317; called by muse, mutect2
- POTEJ | c.2246G>A p.W749* | Nonsense Mutation (SNP) | VAF 70/612 reads (11%) | catalogued as rs771863872; called by muse, mutect2, varscan2
- POU5F1B | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 77/641 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1391626654; called by muse, mutect2, varscan2
- PPFIA4 | c.1526C>T p.S509L (on ENST00000447715; = p.S484L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/393 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs780895208; called by muse, mutect2, varscan2
- PPP1R42 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100221023, COSV61207368; called by muse, mutect2, varscan2
- PPP2R2B | c.1000G>A p.E334K (on ENST00000394409; = p.E400K on NM_181674.2) | Missense Mutation (SNP) | VAF 43/386 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV60771285; called by muse, mutect2, varscan2
- PRAMEF1 | c.293G>A p.W98* | Nonsense Mutation (SNP) | VAF 28/115 reads (24%) | catalogued as rs763270899, COSV60009056; called by muse, mutect2, varscan2
- PRDM1 | c.1784G>A p.R595K | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64845239; called by muse, mutect2
- PRG4 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 78/776 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100798142; called by muse, mutect2, varscan2
- PRG4 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 66/395 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.024); catalogued as rs1030787159, COSV63355420; called by muse, mutect2, varscan2
- PRKCH | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 44/381 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs1445771553; called by muse, mutect2, varscan2
- PRKCQ | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 30/319 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV54106217; called by muse, mutect2
- PROS1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs373983977, CM064172, COSV67777518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRSS35 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 70/543 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV63800612; called by muse, mutect2
- PRSS37 | c.681G>A p.W227* | Nonsense Mutation (SNP) | VAF 36/286 reads (13%) | catalogued as COSV63340237; called by muse, varscan2
- PRSS58 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201700029; called by muse, mutect2, varscan2
- PRTG | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 40/379 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1372142654; called by muse, mutect2, varscan2
- PSD4 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 58/476 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV99830764; called by muse, mutect2, varscan2
- PSMB9 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 52/351 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.191); catalogued as rs759505406; called by muse, varscan2
- PTCHD1 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 50/450 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs375988064, COSV65058676; called by muse, mutect2, varscan2
- PTCHD4 | c.668G>A p.W223* | Nonsense Mutation (SNP) | VAF 46/526 reads (9%) | catalogued as COSV100260581; called by muse, mutect2
- PTGER2 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55418191; called by muse, mutect2, varscan2
- PTGFR | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.213); catalogued as rs267598731, COSV66115132, COSV66115387; called by muse, varscan2
- PTGFR | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1289806791, COSV66114829; called by muse, varscan2
- PTGFR | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267598732, COSV66114849; called by muse, mutect2, varscan2
- PTPN13 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 56/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs374521472; called by muse, mutect2, varscan2
- PTPRK | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 74/509 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs369678964; called by muse, mutect2, varscan2
- PTPRT | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 36/305 reads (12%) | catalogued as COSV62015328; called by muse, mutect2, varscan2
- PTX4 | c.415G>A p.E139K (on ENST00000447419 / NM_001328608.2; = p.E134K on NM_001013658.1) | Missense Mutation (SNP) | VAF 84/586 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV53516672; called by muse, mutect2, varscan2
- PWWP3B | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 78/491 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.895); catalogued as COSV61798612; called by muse, mutect2, varscan2
- PWWP3B | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1569368779, COSV100531673; called by muse, mutect2, varscan2
- PYHIN1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100932383; called by muse, mutect2, varscan2
- RAB3C | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51431364; called by muse, varscan2
- RAB3IP | c.751G>A p.E251K (on ENST00000550536 / NM_175623.4; = p.E235K on NM_022456.5) | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56083281, COSV99923722; called by muse, mutect2, varscan2
- RADX | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 70/608 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1167035780, COSV100998873; called by muse, mutect2, varscan2
- RAPGEF3 | c.845C>T p.S282L (on ENST00000389212; = p.S240L on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754866777, COSV50235284; called by muse, mutect2, varscan2
- RASA2 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 35/288 reads (12%) | catalogued as rs147826658; called by muse, mutect2, varscan2
- RBM11 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.49); catalogued as rs188323297; called by muse, mutect2
- RBM44 | c.531G>A p.W177* (on ENST00000611254; = p.W811* on NM_001080504.2) | Nonsense Mutation (SNP) | VAF 30/263 reads (11%) | catalogued as rs1267759970, COSV57632720; called by muse, mutect2, varscan2
- RBM5 | c.1072T>C p.Y358H | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as rs773254226; called by muse, mutect2
- REG1B | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.321); catalogued as rs1344096935; called by muse, mutect2
- RELN | c.7777G>A p.G2593S | Missense Mutation (SNP) | VAF 59/460 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.327); catalogued as rs888429266; called by muse, varscan2
- RGL3 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66512412; called by muse, varscan2
- RGN | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 41/397 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1458707360; called by muse, mutect2, varscan2
- RGS9 | c.687C>T p.I229= | Splice Region (SNP) | VAF 40/308 reads (13%) | catalogued as rs371275167; called by muse, mutect2, varscan2
- RHD | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 53/427 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.513); catalogued as rs1164589620, CM158945; called by muse, mutect2, varscan2
- RIMBP3B | c.4604G>A p.G1535E | Missense Mutation (SNP) | VAF 66/1263 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs759130241; called by muse, mutect2
- RIMS2 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 39/325 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291849469; called by muse, mutect2, varscan2
- RNF17 | c.3991C>T p.P1331S | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV99693286; called by muse, mutect2
- RORB | c.1063G>A p.D355N (on ENST00000396204 / NM_001365023.1; = p.D344N on NM_006914.4) | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs757356357; called by muse, mutect2
- RP1 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV55123585; called by muse, mutect2, varscan2
- RP1 | c.4846G>A p.E1616K | Missense Mutation (SNP) | VAF 56/396 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs868089931, COSV55115574; called by muse, varscan2
- RP1 | c.4942C>T p.P1648S | Missense Mutation (SNP) | VAF 51/389 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs267601952, COSV55119319; called by muse, varscan2
- RPL22L1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs1313186757, COSV55557092, COSV55557427; called by muse, mutect2, varscan2
- RPS6KA3 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 60/433 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65387153; called by muse, mutect2, varscan2
- RSBN1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as rs755955633, COSV54731394; called by muse, mutect2, varscan2
- RYR1 | c.8551C>T p.P2851S | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs750753962; called by muse, mutect2
- RYR3 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 23/264 reads (9%) | catalogued as rs1210893779, COSV66777286; called by muse, mutect2
- RYR3 | c.4288G>A p.E1430K | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs1011449666, COSV66799659; called by muse, mutect2
- SACS | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 55/405 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV66537580; called by muse, mutect2, varscan2
- SAFB2 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV53042022; called by muse, mutect2, varscan2
- SALL3 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1037339039; called by muse, mutect2, varscan2
- SAMD12 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59050983; called by muse, mutect2
- SAMD9L | c.2768C>T p.S923F | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV59082975; called by muse, mutect2
- SAP130 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 38/428 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.028); catalogued as COSV52101653; called by muse, mutect2
- SARDH | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757833458; called by muse, mutect2, varscan2
- SCCPDH | c.936C>T p.F312= | Splice Region (SNP) | VAF 28/248 reads (11%) | catalogued as rs367677711; called by muse, mutect2, varscan2
- SCNN1G | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 44/472 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs757165262, COSV55598412; called by muse, mutect2
- SDR16C5 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV58126151; called by muse, mutect2, varscan2
- SELENOP | c.534+1G>A p.X178_splice | Splice Site (SNP) | VAF 51/264 reads (19%) | catalogued as COSV62792450; called by muse, mutect2, varscan2
- SEMA5A | c.1761G>A p.M587I | Missense Mutation (SNP) | VAF 83/436 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1252007961; called by muse, mutect2, varscan2
- SEMG2 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 56/400 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs867936565, COSV65647922; called by muse, mutect2, varscan2
- SERPINA10 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 67/491 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs267604109, COSV56228009; called by muse, mutect2, varscan2
- SERPINB10 | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53073480; called by muse, mutect2, varscan2
- SERPINB4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 56/475 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61984761; called by muse, mutect2, varscan2
- SERTAD2 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 49/444 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs766714014; called by muse, mutect2, varscan2
- SFSWAP | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 58/606 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs759197830, COSV55522486; called by muse, mutect2
- SGMS1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.053); catalogued as rs759744291, COSV62371277; called by muse, mutect2
- SH3BGRL | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64623012; called by muse, varscan2
- SH3TC2 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 134/583 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1187551270, COSV60461578; called by muse, mutect2, varscan2
- SHANK2 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 52/421 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV53614801; called by muse, mutect2, varscan2
- SI | c.1827G>A p.W609* | Nonsense Mutation (SNP) | VAF 46/456 reads (10%) | catalogued as rs755917203, COSV52271950; called by muse, mutect2
- SLC13A4 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs765859646; called by muse, mutect2, varscan2
- SLC18A2 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53692275; called by muse, mutect2, varscan2
- SLC22A24 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV70301156, COSV70302909; called by muse, mutect2, varscan2
- SLC25A47 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 51/355 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763583374, COSV100690145; called by muse, mutect2, varscan2
- SLC26A3 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 62/451 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100384863; called by muse, mutect2, varscan2
- SLC2A9 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs746265337, COSV99303491; called by muse, mutect2, varscan2
- SLC44A5 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 44/428 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs138689403, COSV63758541; called by muse, mutect2
- SLC4A2 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 50/439 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs747111630; called by muse, mutect2, varscan2
- SLC5A6 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 48/435 reads (11%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.006); catalogued as COSV100143547; called by muse, mutect2, varscan2
- SLC5A7 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 65/424 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50891737; called by muse, mutect2, varscan2
- SLC8A3 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.06); catalogued as COSV100776426; called by muse, mutect2, varscan2
- SLC9A4 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs757993605; called by muse, mutect2, varscan2
- SLCO1A2 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 48/470 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1036836139; called by muse, mutect2
- SLFN12 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 47/554 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs1449775547, COSV59225748; called by muse, mutect2
- SLIT3 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 63/439 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV60593988; called by muse, mutect2, varscan2
- SLTM | c.1894C>T p.R632* | Nonsense Mutation (SNP) | VAF 29/322 reads (9%) | catalogued as COSV51053895; called by muse, mutect2
- SMOC2 | c.1267G>A p.D423N (on ENST00000356284 / NM_001166412.2; = p.D434N on NM_022138.3) | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV62438731; called by muse, mutect2, varscan2
- SMURF1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777247584, COSV63158700; called by muse, mutect2, varscan2
- SNAP91 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV52124740; called by muse, mutect2
- SNRNP200 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1462267105; called by muse, mutect2, varscan2
- SNX30 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1187544467; called by muse, mutect2, varscan2
- SOGA3 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV64106127; called by muse, mutect2
- SORBS2 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 52/530 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1206275528, COSV53004542; called by muse, mutect2
- SORBS3 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 28/335 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.28); catalogued as rs753866090; called by muse, mutect2
- SORL1 | c.3050G>A p.G1017E | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52759340; called by muse, mutect2, varscan2
- SP1 | c.2330C>T p.S777F (on ENST00000327443 / NM_138473.3; = p.S770F on NM_003109.1) | Missense Mutation (SNP) | VAF 42/415 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV100540851; called by muse, mutect2
- SP140L | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 31/274 reads (11%) | catalogued as COSV54742288; called by muse, mutect2, varscan2
- SPDEF | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 50/477 reads (10%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.355); catalogued as COSV65000649; called by muse, mutect2, varscan2
- SPEF2 | c.2927G>A p.G976E | Missense Mutation (SNP) | VAF 26/317 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV61547466; called by muse, mutect2
1,957 further variants in this file (956 protein-altering or splice-affecting, 904 silent, 97 other) are not listed here.
